Surgical pathology report (de-identified scan), TCGA case TCGA-SI-A71O, project TCGA-SARC (Sarcoma), tissue source site Washington University St. Louis, specimen TCGA-SI-A71O-06A (Metastatic).

[page 1 of 3]
Patient Name: [REDACTED]

DOB: [REDACTED]

Surgical Pathology Report

Final

SURGICAL PATHOLOGY REPORT

FINAL

Patient Name: [REDACTED]

Address: [REDACTED]

Service:

Cardiothoracic Surgery

Accession # [REDACTED]

Taken:

Gender: [REDACTED]

DOB: [REDACTED]

MRN: [REDACTED]

Hospital #: [REDACTED]

Patient Type: [REDACTED]

Received:

Accessioned:

Reported:

Physician(s):

DIAGNOSIS:

LUNG, LEFT UPPER LOBE, WEDGE RESECTION #1 (INCLUDING FS1)

- UNDIFFERENTIATED SARCOMA, 0.5 CM IN GREATEST DIMENSION
- TUMOR NOT PRESENT AT RESECTION MARGIN
- SEE COMMENT

LUNG, LEFT UPPER LOBE, WEDGE RESECTION #2 (INCLUDING FS2)

- UNDIFFERENTIATED SARCOMA, 1.2 CM IN GREATEST DIMENSION
- TUMOR INVADERS THE PLEURA AND IS PRESENT AT THE INKED PLEURAL SURFACE
- TUMOR NOT PRESENT AT RESECTION MARGIN
- SEE COMMENT

LUNG, LEFT LOWER LOBE, WEDGE RESECTION (INCLUDING FS3)

- UNDIFFERENTIATED SARCOMA, 1.3 CM IN GREATEST DIMENSION
- TUMOR ABUTS THE PLEURA
- TUMOR NOT PRESENT AT RESECTION MARGIN
- SEE COMMENT

ICD-10-3

*Tumor, peripheral nerve sheath malignant
Site: Lung, upper lobe C34.1
9546/3
7/25/14*

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis).

***Report Electronically Reviewed and signed Out by

Intraoperative Consultation:

FS1: An intraoperative non-microscopic consultation was obtained and interpreted as: "Called to pick up (left upper lobe wedge #1) is a triangular stapled wedge of lung measuring 4 x 1.5 x 1 cm. Staple line is removed and inked, inked blue, and shaved off. Frozen as FS1A. Remainder including white firm lesion measuring 0.3 cm, sectioned and frozen as FS1B," by

FS2: An intraoperative non-microscopic consultation was obtained and interpreted as: "Called to pick up 'left upper lobe wedge resection #2' consisting of 4.65 gm, 5.5 x 2.3 x 0.4 cm wedge of lung with a tan-white, 1.2 x 1 x 1 x 0.6 cm

[page 2 of 3]
Patient Name: [REDACTED]

DOB: [REDACTED]

MRN: [REDACTED]

Patient ID: [REDACTED]

[REDACTED] mass putatively ulcerating through the pleura, located 1.2 cm from margin. Pleural surface is inked green, staple margin removed and adjacent parenchyma is inked black. Representative sections of the mass frozen as FS2 in relation to margin. Rest for permanents," by [REDACTED]

FS3: An intraoperative non-microscopic consultation was obtained and interpreted as: "Called to pick up 'left lower lobe wedge' consisting of a lung wedge measuring 5 x 2 x 1.4 cm, with a tan-white 1.3 x 0.9 x 0.7 cm ovoid mass abutting the pleura. It is located 1.3 cm from the stapled margin. The resection margin is inked blue. Representative sections of the mass are frozen as FS3A and a shave of staple margin close to the mass is frozen as FS3B. Rest for permanents," by [REDACTED]

FS1A: Left upper lobe wedge #1 margin
- "No evidence of malignancy," by [REDACTED]

FS1B: Left upper lobe wedge lesion #1
- "High grade malignant neoplasm," by [REDACTED]

FS2: Left upper lobe wedge #2 lesion in relation to margin:
- "High grade malignant neoplasm,"
- "Margin free of tumor," by [REDACTED]

FS3: Left lower lobe lesion
- "High grade malignant neoplasm," by [REDACTED]

FS3B: Left lower lobe margin
- "No evidence of malignancy," by [REDACTED]

Microscopic Description and Comment:

The patient's previous right hip mass resection slides [REDACTED] are reviewed. The current lung nodules are histologically similar to the tumor from the patient's previous hip resection and are consistent with metastatic malignant peripheral nerve sheath tumor.

For lung upper lobe wedge resection #1, the actual frozen sections of the shave margin show no evidence of malignancy. There is tumor present in the permanent sections, representing deeper samples of A1.

History:

The patient is a [REDACTED] year old man with multiple left lung nodules. Operative procedure: Left video-assisted thoracic surgery, wedge resection.

Specimen(s) Received:

A: LEFT UPPER LOBE WEDGE RESECTION #1
B: LEFT UPPER LOBE WEDGE RESECTION #2
C: LEFT LOWER LOBE WEDGE

Gross Description:

The specimens are received in three formalin-filled containers, each labeled [REDACTED]. The first container is labeled "left upper lobe wedge #1" and it contains two green cassettes with frozen section remnants. The frozen section remnant corresponds to the gross intraoperative nonmicroscopic description "triangular stapled wedge of lung measuring 4 x 1.5 x 1 cm, showing a lesion measuring 0.3 cm." Labeled A1 - frozen section remnant 1A; A2 - frozen section remnant 1B. Jar 1.

[page 3 of 3]
Patient Name: [REDACTED]

DOB: [REDACTED]

The second container is labeled "left upper lobe wedge resection #2" and it contains a green cassette with frozen section tissue remnant and rest of the wedge resection specimen. It is grossly consistent with a description in the intraoperative consultation "5.5 x 2.3 x 0.4 cm wedge of lung with a tan white 1.2 x 1 x 0.6 cm mass putatively ulcerating through the pleura. Resection margin is inked blue." Labeled B1 - frozen section remnant; FS2; B2 sections of residual mass; B3 - uninvolved lung. Jar 1.

The third container is labeled "left lower lobe wedge" and it consists of previously dissected wedge resection of lung and two frozen section remnant cassettes labeled FS3A and FS3B. The gross findings are consistent as described in the intraoperative consultation "lung wedge measuring 5 x 2 x 1.4 cm with a tan-white 1.3 x 0.9 x 0.7 cm ovoid mass abutting the pleura. The mass is located 1.3 cm from staple resection margin. The mass is frozen as FS3A and a shave of the margin adjacent to the mass frozen as FS3B." Labeled C1 - frozen section remnants; FS3A; C2 - frozen section remnant FS3B; C3 - Rest of the mass. Jar 1.

Surgical Pathology report is available on-line on

Recurrent submission to primary
of h.p.

END OF REPORT

Page 3 of 3

Source: NCI Genomic Data Commons file 0f1c7d02-8c7b-48ef-aad9-933599de53b4 (TCGA-SI-A71O.3EBC299A-8A60-46FC-8B6E-EC3F8A5D19CB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).